Somatic mutation profile of tumor specimen TCGA-ET-A39I-01A (aliquot TCGA-ET-A39I-01A-11D-A19J-08) from TCGA case TCGA-ET-A39I, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 83.1 years (30,349 days).
Specimen TCGA-ET-A39I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17958270-ae8a-4a67-b038-9f868849723f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39I-10A (Blood Derived Normal), aliquot TCGA-ET-A39I-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94cf82b9-ebbc-4a10-89ed-06f1d8ca75a6

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 43/98 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATG2B | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs752233077, COSV63423946; called by muse, mutect2, varscan2
- BPTF | c.7270G>T p.E2424* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV58839851; called by muse, mutect2
- EPG5 | c.4940A>G p.E1647G | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56351444; called by muse, mutect2, varscan2
- MEPCE | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52769403; called by muse, varscan2
- MLLT1 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV53131309; called by muse, mutect2, varscan2
- TCF7L1 | c.1354A>T p.K452* | Nonsense Mutation (SNP) | VAF 123/303 reads (41%) | catalogued as COSV56399856; called by muse, mutect2, varscan2
- ZNF148 | c.1883T>G p.L628R | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV62305450; called by muse, mutect2, varscan2
- ZNF777 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56098512; called by muse, mutect2, varscan2
- KLHL41 | c.1041A>T p.I347= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV52930680; called by muse, mutect2, varscan2
- SLC6A16 | c.807C>T p.V269= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs1209359644, COSV60028477; called by muse, mutect2, varscan2
